Somatic mutation profile of tumor specimen C3L-01033-03 (aliquot CPT0170070006) from CPTAC case C3L-01033, project CPTAC-3 (Kidney — Adenomas and Adenocarcinomas). Sex at birth: male; Vital status: Alive; Primary diagnosis: Renal cell carcinoma, NOS; Tissue or organ of origin: Kidney, NOS; AJCC pathologic stage: Stage II; Tumor grade: G3; Age at diagnosis: 70.4 years (25,703 days).
Specimen C3L-01033-03: Sample type: Primary Tumor; Tissue type: Tumor; Tumor descriptor: Primary; Specimen type: Solid Tissue; Biospecimen anatomic site: Kidney; Preservation method: Snap Frozen.
Source: NCI Genomic Data Commons open-access Masked Somatic Mutation file (Mutation Annotation Format, MAF) 882c0317-377b-4fb4-876a-652f86697848.wxs.aliquot_ensemble_masked.maf.gz, workflow Aliquot Ensemble Somatic Variant Merging and Masking; Data Release 46.0 - August 10, 2026. Variants were called in the tumor against matched normal specimen C3L-01033-31 (Blood Derived Normal), aliquot CPT0167210002; read counts below are tumor reads.
https://portal.gdc.cancer.gov/files/9cd365db-4b53-424b-8a97-556e727a51a0

The open-access MAF lists 78 somatic variants for this specimen: 63 protein-altering or splice-affecting, 6 silent, 9 other (UTR, intronic, flanking, RNA and similar).
By variant classification: Missense Mutation 41, Frame Shift Del 9, Intron 6, Nonsense Mutation 6, Silent 6, Splice Site 3, 5'Flank 2, Frame Shift Ins 2, Splice Region 1, 3'UTR 1, In Frame Del 1.

Variants (all; order: hotspot or ClinVar-pathogenic variants first, then other protein-altering variants with a dbSNP/COSMIC/ClinVar record ('catalogued as' / 'ClinVar'), then the remaining protein-altering, then silent, then non-coding — alphabetical by gene within each group; each line: gene | DNA and protein change | classification | tumor variant allele fraction (VAF) | annotations). Protein positions are numbered on GDC's canonical Ensembl transcript (GENCODE v36); where an older RefSeq transcript numbers the protein differently, the line names both transcripts and gives that numbering too:
- TSC1 | c.733C>T p.R245* | Nonsense Mutation (SNP) | VAF 63/417 reads (15%) | catalogued as rs118203434, CM981932, COSV53763655, COSV53766104; ClinVar: pathogenic; called by muse, mutect2, varscan2
- VHL | c.477del p.E160Sfs*10 | Frame Shift Del (DEL) | VAF 94/474 reads (20%) | catalogued as rs730882020, CD093920, CM961430, COSV56545604, COSV56548401; ClinVar: pathogenic; called by mutect2, pindel, varscan2
- AKR7A3 | c.301C>T p.R101W | Missense Mutation (SNP) | VAF 48/325 reads (15%) | SIFT deleterious (0); PolyPhen benign (0.311); catalogued as rs775325206; called by muse, mutect2, varscan2
- BEST1 | c.1740-1G>C p.X580_splice | Splice Site (SNP) | VAF 52/368 reads (14%) | catalogued as COSV99861378; called by muse, mutect2, varscan2
- CEP170 | c.3268A>G p.T1090A | Missense Mutation (SNP) | VAF 17/150 reads (11%) | SIFT tolerated (0.27); PolyPhen benign (0.388); catalogued as COSV100316333; called by muse, mutect2, varscan2
- COL21A1 | c.2634del p.S880Afs*24 | Frame Shift Del (DEL) | VAF 18/138 reads (13%) | catalogued as rs1402825108; called by mutect2, pindel
- EPPK1 | c.6910G>T p.E2304* | Nonsense Mutation (SNP) | VAF 14/344 reads (4%) | catalogued as COSV73262038; called by muse, mutect2
- ERBIN | c.814A>G p.I272V | Missense Mutation (SNP) | VAF 28/146 reads (19%) | SIFT tolerated (0.05); PolyPhen benign (0.003); catalogued as rs756303996; called by muse, mutect2, varscan2
- FERMT3 | c.1010C>T p.S337L | Missense Mutation (SNP) | VAF 48/232 reads (21%) | SIFT tolerated (0.08); PolyPhen probably damaging (0.917); catalogued as rs1456223717, COSV54177651; called by muse, mutect2, varscan2
- ITGB4 | c.3508G>A p.E1170K | Missense Mutation (SNP) | VAF 48/347 reads (14%) | SIFT deleterious (0); PolyPhen benign (0.361); catalogued as rs768678559; called by muse, mutect2, varscan2
- KCNC4 | c.1058G>A p.R353H | Missense Mutation (SNP) | VAF 39/208 reads (19%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as rs780991501, COSV63925351; called by muse, mutect2, varscan2
- MYT1L | c.2125G>A p.A709T | Missense Mutation (SNP) | VAF 91/503 reads (18%) | SIFT tolerated (0.67); PolyPhen benign (0.027); catalogued as rs1486325982, COSV101220730; called by muse, mutect2, varscan2
- NPHS1 | c.3202G>A p.A1068T | Missense Mutation (SNP) | VAF 61/330 reads (18%) | SIFT tolerated (0.08); PolyPhen probably damaging (0.926); catalogued as rs146858871; called by muse, mutect2, varscan2
- OR2AE1 | c.943C>T p.R315* | Nonsense Mutation (SNP) | VAF 12/54 reads (22%) | catalogued as rs200086548, COSV104413046; called by muse, varscan2
- OR4S2 | c.358C>T p.R120C | Missense Mutation (SNP) | VAF 21/144 reads (15%) | SIFT deleterious (0.01); PolyPhen benign (0.035); catalogued as rs267602971, COSV56746047; called by muse, mutect2, varscan2
- PCDHA9 | c.1608C>A p.S536R | Missense Mutation (SNP) | VAF 190/1076 reads (18%) | SIFT tolerated, low confidence (0.07); PolyPhen benign (0.088); catalogued as rs782550369; called by muse, mutect2, varscan2
- SERPING1 | c.124G>A p.E42K | Missense Mutation (SNP) | VAF 76/398 reads (19%) | SIFT tolerated (0.87); PolyPhen benign (0.001); catalogued as rs778625408, CM083116, COSV53543478; called by muse, mutect2, varscan2
- A2ML1 | c.1843A>T p.M615L | Missense Mutation (SNP) | VAF 29/146 reads (20%) | SIFT tolerated (1); PolyPhen benign (0); called by muse, varscan2
- ACAN | c.6610G>T p.G2204C | Missense Mutation (SNP) | VAF 84/464 reads (18%) | SIFT deleterious (0); PolyPhen probably damaging (0.997); called by muse, mutect2, varscan2
- AKR1B10 | c.386G>A p.G129D | Missense Mutation (SNP) | VAF 33/220 reads (15%) | SIFT deleterious (0.05); PolyPhen possibly damaging (0.522); called by muse, mutect2, varscan2
- ALOX12B | c.361A>G p.T121A | Missense Mutation (SNP) | VAF 105/627 reads (17%) | SIFT tolerated (0.51); PolyPhen benign (0); called by muse, mutect2, varscan2
- ARHGAP11A | c.2537del p.N846Ifs*29 | Frame Shift Del (DEL) | VAF 25/165 reads (15%) | called by mutect2, pindel, varscan2
- ASTN1 | c.349A>G p.T117A | Missense Mutation (SNP) | VAF 9/65 reads (14%) | SIFT deleterious, low confidence (0); PolyPhen probably damaging (0.987); called by muse, mutect2, varscan2
- ATF6B | c.1550G>A p.S517N | Missense Mutation (SNP) | VAF 31/153 reads (20%) | SIFT tolerated (0.07); PolyPhen possibly damaging (0.843); called by muse, mutect2, varscan2
- ATXN7 | c.1155del p.L385Ffs*2 | Frame Shift Del (DEL) | VAF 44/274 reads (16%) | called by mutect2, pindel, varscan2
- BIN1 | c.1768G>A p.E590K (on ENST00000316724 / NM_001320642.1; = p.E451K on NM_004305.4) | Missense Mutation (SNP) | VAF 65/359 reads (18%) | SIFT tolerated (0.06); PolyPhen probably damaging (0.974); called by muse, mutect2, varscan2
- BRD4 | c.3787C>T p.R1263* | Nonsense Mutation (SNP) | VAF 24/126 reads (19%) | called by muse, mutect2, varscan2
- C20orf194 | c.312C>G p.S104R | Missense Mutation (SNP) | VAF 24/160 reads (15%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.835); called by muse, mutect2
- CACNA1H | c.6161C>G p.S2054C | Missense Mutation (SNP) | VAF 7/28 reads (25%) | SIFT deleterious (0.04); PolyPhen benign (0.257); called by muse, mutect2, varscan2
- CFHR5 | c.340T>G p.C114G | Missense Mutation (SNP) | VAF 42/264 reads (16%) | SIFT deleterious (0); PolyPhen probably damaging (1); called by muse, mutect2, varscan2
- CHST3 | c.381del p.V128Wfs*88 | Frame Shift Del (DEL) | VAF 76/494 reads (15%) | called by mutect2, pindel, varscan2
- DBN1 | c.832-2A>C p.X278_splice | Splice Site (SNP) | VAF 46/270 reads (17%) | called by muse, mutect2, varscan2
- DCLK1 | c.349A>G p.I117V | Missense Mutation (SNP) | VAF 12/92 reads (13%) | SIFT tolerated (0.44); PolyPhen benign (0.044); called by muse, mutect2, varscan2
- DIDO1 | c.6060G>T p.K2020N | Missense Mutation (SNP) | VAF 22/76 reads (29%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.973); called by muse, mutect2, varscan2
- DLGAP1 | c.1320C>G p.S440R | Missense Mutation (SNP) | VAF 26/143 reads (18%) | SIFT deleterious (0.01); PolyPhen benign (0.157); called by muse, mutect2, varscan2
- DLGAP1 | c.1319G>A p.S440N | Missense Mutation (SNP) | VAF 26/150 reads (17%) | SIFT deleterious (0.01); PolyPhen benign (0.148); called by muse, mutect2, varscan2
- DNAH2 | c.8272A>T p.M2758L | Missense Mutation (SNP) | VAF 19/73 reads (26%) | SIFT tolerated (0.23); PolyPhen benign (0.06); called by muse, mutect2, varscan2
- FNDC3A | c.2859T>A p.D953E (on ENST00000492622 / NM_001079673.2; = p.D897E on NM_014923.5) | Missense Mutation (SNP) | VAF 79/517 reads (15%) | SIFT tolerated (1); PolyPhen benign (0.006); called by muse, mutect2, varscan2
- FTH1 | c.230G>T p.R77L | Missense Mutation (SNP) | VAF 68/477 reads (14%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.957); called by muse, mutect2, varscan2
- GPAT3 | c.1054T>C p.Y352H | Missense Mutation (SNP) | VAF 54/286 reads (19%) | SIFT tolerated (0.07); PolyPhen probably damaging (0.996); called by muse, mutect2, varscan2
- GYS1 | c.2098A>T p.T700S | Missense Mutation (SNP) | VAF 38/339 reads (11%) | SIFT tolerated, low confidence (0.57); PolyPhen benign (0); called by muse, mutect2, varscan2
- HNRNPH1 | c.222_225del p.D74Efs*23 | Frame Shift Del (DEL) | VAF 30/203 reads (15%) | called by mutect2, pindel, varscan2
- KDM4D | c.1441T>G p.C481G | Missense Mutation (SNP) | VAF 10/59 reads (17%) | SIFT tolerated, low confidence (0.31); PolyPhen benign (0); called by muse, mutect2, varscan2
- LPA | c.4545del p.T1516Pfs*14 | Frame Shift Del (DEL) | VAF 38/272 reads (14%) | called by mutect2, pindel, varscan2
- LPIN2 | c.659A>T p.H220L | Missense Mutation (SNP) | VAF 28/149 reads (19%) | SIFT tolerated (0.65); PolyPhen benign (0.075); called by muse, mutect2, varscan2
- MUC16 | c.34943C>A p.T11648N | Missense Mutation (SNP) | VAF 68/400 reads (17%) | SIFT deleterious, low confidence (0.04); PolyPhen possibly damaging (0.654); called by muse, mutect2, varscan2
- MXRA5 | c.7463C>A p.A2488D | Missense Mutation (SNP) | VAF 16/191 reads (8%) | SIFT deleterious (0); PolyPhen probably damaging (1); called by muse, mutect2
- OR1F1 | c.346G>A p.A116T | Missense Mutation (SNP) | VAF 45/289 reads (16%) | SIFT tolerated (0.35); PolyPhen benign (0.033); called by muse, mutect2, varscan2
- PAPPA2 | c.4241del p.P1414Qfs*4 | Frame Shift Del (DEL) | VAF 38/291 reads (13%) | called by mutect2, pindel, varscan2
- PARP2 | c.46+2T>A p.X16_splice | Splice Site (SNP) | VAF 38/185 reads (21%) | called by muse, mutect2, varscan2
- PBRM1 | c.2707G>T p.E903* | Nonsense Mutation (SNP) | VAF 52/263 reads (20%) | called by muse, mutect2, varscan2
- PLXNA3 | c.3069_3070insT p.T1024Yfs*6 | Frame Shift Ins (INS) | VAF 12/34 reads (35%) | called by mutect2, varscan2
- POLR3H | c.89T>C p.L30P | Missense Mutation (SNP) | VAF 26/473 reads (5%) | SIFT deleterious (0); PolyPhen probably damaging (0.995); called by muse, mutect2
- RBM14 | c.650T>A p.L217Q | Missense Mutation (SNP) | VAF 42/212 reads (20%) | SIFT deleterious (0); PolyPhen possibly damaging (0.806); called by muse, mutect2, varscan2
- REN | c.256T>C p.Y86H | Missense Mutation (SNP) | VAF 4/26 reads (15%) | SIFT deleterious (0); PolyPhen probably damaging (1); called by muse, mutect2
- SH3BP2 | c.724_739del p.H242Lfs*31 | Frame Shift Del (DEL) | VAF 32/210 reads (15%) | called by mutect2, pindel
- SLC4A3 | c.2190G>A p.L730= | Splice Region (SNP) | VAF 8/28 reads (29%) | called by muse, mutect2, varscan2
- TCTN3 | c.629C>T p.A210V | Missense Mutation (SNP) | VAF 25/150 reads (17%) | SIFT tolerated (0.16); PolyPhen possibly damaging (0.71); called by muse, mutect2, varscan2
- TIMELESS | c.2890A>T p.K964* | Nonsense Mutation (SNP) | VAF 10/210 reads (5%) | called by muse, mutect2
- WDR90 | c.648_650del p.D217del | In Frame Del (DEL) | VAF 46/317 reads (15%) | called by mutect2, pindel, varscan2
- WRN | c.3080T>A p.F1027Y | Missense Mutation (SNP) | VAF 62/398 reads (16%) | SIFT tolerated (0.32); PolyPhen benign (0.116); called by muse, mutect2, varscan2
- WWC2 | c.2175dup p.H726Sfs*14 | Frame Shift Ins (INS) | VAF 29/208 reads (14%) | called by mutect2, pindel, varscan2
- XIAP | c.267T>G p.N89K | Missense Mutation (SNP) | VAF 7/108 reads (6%) | SIFT tolerated (0.05); PolyPhen benign (0.079); called by muse, mutect2
- CFAP46 | c.1125C>T p.G375= | Silent (SNP) | VAF 15/65 reads (23%) | catalogued as rs553427965; called by muse, mutect2
- GPR149 | c.897C>T p.T299= | Silent (SNP) | VAF 57/292 reads (20%) | catalogued as rs763492132; called by muse, mutect2, varscan2
- HMCN2 | c.13950C>T p.F4650= | Silent (SNP) | VAF 66/271 reads (24%) | called by muse, mutect2, varscan2
- KCNB2 | c.618C>T p.S206= | Silent (SNP) | VAF 29/136 reads (21%) | catalogued as COSV101578800; called by muse, mutect2, varscan2
- PRPF8 | c.6222G>A p.R2074= | Silent (SNP) | VAF 122/671 reads (18%) | called by muse, mutect2, varscan2
- TESK1 | c.804C>T p.G268= | Silent (SNP) | VAF 28/121 reads (23%) | called by muse, mutect2, varscan2
- C2CD6 | c.1581+2982C>A | Intron (SNP) | VAF 9/61 reads (15%) | called by muse, mutect2, varscan2
- CLN5 | c.*412_*414delinsG | 3'UTR (DEL) | VAF 12/57 reads (21%) | called by pindel, varscan2*
- MIA3 | c.3478-1040T>C | Intron (SNP) | VAF 49/398 reads (12%) | called by muse, mutect2
- MIA3 | c.3478-1038C>A | Intron (SNP) | VAF 51/400 reads (13%) | called by muse, mutect2
- PTPA | c.999+163C>A | Intron (SNP) | VAF 47/226 reads (21%) | called by muse, mutect2, varscan2
- PXN | c.14-2006G>T | Intron (SNP) | VAF 36/254 reads (14%) | called by muse, mutect2, varscan2
- SPATA21 | c.35-3205C>A | Intron (SNP) | VAF 27/135 reads (20%) | catalogued as rs557944645; called by muse, mutect2, varscan2
- SSU72 | chr1:1575178 C>T | 5'Flank (SNP) | VAF 65/452 reads (14%) | called by muse, mutect2, varscan2
- TLE5 | chr19:3062886 del G | 5'Flank (DEL) | VAF 27/180 reads (15%) | called by mutect2, pindel, varscan2
